Somatic mutation profile of tumor specimen MMRF_2535_2_BM_CD138pos (aliquot MMRF_2535_2_BM_CD138pos_T1_KHS5U_L15787) from MMRF case MMRF_2535, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: female; Vital status: Dead; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow; Age at diagnosis: 46.6 years (17,034 days).
Specimen MMRF_2535_2_BM_CD138pos: Sample type: Recurrent Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Recurrence; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) ccd78840-f3cc-4ae0-90e0-d872f0cc08b3.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_2535_1_PB_WBC (Blood Derived Normal), aliquot MMRF_2535_1_PB_WBC_C3_KHS5U_L13315; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/d9a9b7c1-3fe2-4d02-a771-bbfc9a719809

The open-access MAF lists 142 somatic variants for this specimen: 50 protein-altering or splice-affecting, 20 silent, 72 other (UTR, intronic, flanking, RNA and similar).
By variant classification: 3'UTR 43, Missense Mutation 43, Silent 20, Intron 11, RNA 6, 5'Flank 5, 5'UTR 5, Nonsense Mutation 3, 3'Flank 2, Splice Region 2, Translation Start Site 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ASB18 | c.49G>A p.V17M | Missense Mutation (SNP) | VAF 46/216 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV68960571; called by muse, mutect2, varscan2
- BDP1 | c.5021C>T p.S1674L | Missense Mutation (SNP) | VAF 9/83 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.048); catalogued as COSV100703529; called by muse, mutect2, varscan2
- C3orf20 | c.836G>A p.C279Y | Missense Mutation (SNP) | VAF 10/41 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53787098; called by muse, mutect2, varscan2
- CCNI2 | c.615A>C p.K205N | Missense Mutation (SNP) | VAF 35/164 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs548714263; called by muse, mutect2, varscan2
- CHD2 | c.2782C>T p.R928W | Missense Mutation (SNP) | VAF 8/88 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as rs765497208, COSV67708564; called by muse, mutect2, varscan2
- CTNNA2 | c.886G>A p.E296K | Missense Mutation (SNP) | VAF 16/120 reads (13%) | SIFT deleterious (0.05); PolyPhen benign (0.251); catalogued as COSV100786959; called by muse, varscan2
- EP400 | c.2677C>T p.L893= | Splice Region (SNP) | VAF 22/169 reads (13%) | catalogued as rs773438145, COSV100202134; called by muse, mutect2, varscan2
- FOXP4 | c.1886C>T p.P629L (on ENST00000307972 / NM_001012426.1; = p.P616L on NM_138457.3) | Missense Mutation (SNP) | VAF 3/24 reads (13%) | SIFT tolerated (0.97); PolyPhen benign (0.003); catalogued as rs1386450589; called by muse, mutect2
- KIF25 | c.595C>T p.H199Y | Missense Mutation (SNP) | VAF 6/84 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100596223; called by muse, mutect2
- NUP88 | c.652G>A p.E218K | Missense Mutation (SNP) | VAF 28/203 reads (14%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.993); catalogued as rs201799531; called by muse, mutect2, varscan2
- OPN1LW | c.697G>A p.A233T | Missense Mutation (SNP) | VAF 49/266 reads (18%) | SIFT tolerated (0.36); PolyPhen benign (0.009); catalogued as rs781936473, CM045802, COSV100885039, COSV64049532; called by muse, mutect2, varscan2
- OR5AK2 | c.117A>G p.I39M | Missense Mutation (SNP) | VAF 45/255 reads (18%) | SIFT tolerated (0.3); PolyPhen benign (0.011); catalogued as rs1471551552; called by muse, mutect2, varscan2
- RAD51C | c.1096C>G p.R366G | Missense Mutation (SNP) | VAF 36/420 reads (9%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.678); catalogued as COSV100507059; called by muse, mutect2
- SF3B3 | c.995C>G p.T332S | Missense Mutation (SNP) | VAF 45/278 reads (16%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.838); catalogued as COSV100209881; called by muse, mutect2, varscan2
- SIPA1L3 | c.154G>A p.E52K | Missense Mutation (SNP) | VAF 12/75 reads (16%) | SIFT tolerated (0.43); PolyPhen benign (0.083); catalogued as rs753429177, COSV55917980; called by muse, mutect2, varscan2
- SLC9A2 | c.1843C>T p.R615* | Nonsense Mutation (SNP) | VAF 9/69 reads (13%) | catalogued as rs770829784; called by muse, mutect2, varscan2
- TAMM41 | c.638G>A p.R213Q | Missense Mutation (SNP) | VAF 39/198 reads (20%) | SIFT tolerated (0.19); PolyPhen benign (0.351); catalogued as rs760435126; called by muse, mutect2, varscan2
- TNXB | c.10283C>G p.S3428W (on ENST00000647633; = p.S3181W on NM_019105.8 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 5/23 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs756035213; called by muse, mutect2, varscan2
- TPCN2 | c.1587C>T p.G529= | Splice Region (SNP) | VAF 13/85 reads (15%) | catalogued as rs1174741889; called by muse, mutect2, varscan2
- ZDBF2 | c.6377C>T p.S2126F | Missense Mutation (SNP) | VAF 42/184 reads (23%) | SIFT deleterious (0.02); PolyPhen benign (0.098); catalogued as rs1559163082, COSV65629755; called by muse, mutect2, varscan2
- ZFHX3 | c.1670C>T p.S557F | Missense Mutation (SNP) | VAF 21/128 reads (16%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.624); catalogued as COSV51714212; called by muse, mutect2, varscan2
- ADAT3 | c.974G>A p.G325D | Missense Mutation (SNP) | VAF 19/96 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ALOXE3 | c.43A>T p.R15W | Missense Mutation (SNP) | VAF 10/58 reads (17%) | SIFT tolerated (0.18); PolyPhen benign (0.185); called by muse, mutect2, varscan2
- ASAP1 | c.3346A>G p.K1116E | Missense Mutation (SNP) | VAF 35/185 reads (19%) | SIFT deleterious (0.01); PolyPhen benign (0.055); called by muse, mutect2, varscan2
- B4GALT6 | c.739C>A p.R247S | Missense Mutation (SNP) | VAF 27/146 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); called by muse, mutect2, varscan2
- BICRA | c.4382A>C p.D1461A | Missense Mutation (SNP) | VAF 15/89 reads (17%) | SIFT deleterious (0.02); PolyPhen benign (0.025); called by muse, mutect2
- BICRA | c.4427A>T p.K1476M | Missense Mutation (SNP) | VAF 15/103 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- DDHD1 | c.121G>A p.E41K (on ENST00000323669; = p.E272K on NM_030637.3) | Missense Mutation (SNP) | VAF 35/236 reads (15%) | SIFT tolerated (0.48); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- DHRS7 | c.983C>G p.S328C | Missense Mutation (SNP) | VAF 35/222 reads (16%) | SIFT tolerated (0.17); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- EFHD1 | c.101C>T p.P34L | Missense Mutation (SNP) | VAF 8/28 reads (29%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0); called by muse, mutect2
- FAM184B | c.1103T>A p.L368H | Missense Mutation (SNP) | VAF 23/163 reads (14%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- FEM1C | c.787C>T p.L263F | Missense Mutation (SNP) | VAF 63/296 reads (21%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.764); called by muse, mutect2, varscan2
- GFY | c.298G>A p.E100K | Missense Mutation (SNP) | VAF 42/211 reads (20%) | SIFT tolerated (0.2); PolyPhen benign (0.031); called by muse, varscan2
- KAZN | c.1148T>G p.M383R | Missense Mutation (SNP) | VAF 39/182 reads (21%) | SIFT tolerated (0.27); PolyPhen probably damaging (0.974); called by muse, mutect2, varscan2
- KBTBD6 | c.31C>T p.R11C | Missense Mutation (SNP) | VAF 26/100 reads (26%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- MAP2 | c.1945C>A p.P649T | Missense Mutation (SNP) | VAF 33/220 reads (15%) | SIFT deleterious (0.04); PolyPhen benign (0.265); called by muse, mutect2, varscan2
- MAP2 | c.1946C>A p.P649H | Missense Mutation (SNP) | VAF 33/222 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.87); called by muse, mutect2, varscan2
- MORF4L1 | c.61C>T p.H21Y | Missense Mutation (SNP) | VAF 6/38 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2
- NMRK1 | c.3G>A p.M1? | Translation Start Site (SNP) | VAF 34/234 reads (15%) | SIFT deleterious (0.02); PolyPhen benign (0.239); called by muse, mutect2, varscan2
- PDE6B | c.886G>C p.E296Q | Missense Mutation (SNP) | VAF 23/176 reads (13%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.984); called by muse, mutect2, varscan2
- RNF180 | c.1048G>C p.E350Q | Missense Mutation (SNP) | VAF 18/140 reads (13%) | SIFT tolerated (0.68); PolyPhen benign (0.069); called by mutect2, varscan2
- TMEM52B | c.54+2T>C p.X18_splice (on ENST00000381923 / NM_001079815.1; = p.X13_splice on NM_153022.4) | Splice Site (SNP) | VAF 29/168 reads (17%) | called by muse, varscan2
- TRAM1L1 | c.956G>T p.W319L | Missense Mutation (SNP) | VAF 26/327 reads (8%) | SIFT deleterious (0); PolyPhen benign (0.103); called by muse, mutect2
- TSPO2 | c.222G>A p.W74* | Nonsense Mutation (SNP) | VAF 4/92 reads (4%) | called by muse, mutect2
- USP6NL | c.1655A>G p.D552G | Missense Mutation (SNP) | VAF 31/179 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- ZC3H7A | c.442A>G p.K148E | Missense Mutation (SNP) | VAF 17/141 reads (12%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.459); called by muse, mutect2, varscan2
- ZNF234 | c.921C>A p.C307* | Nonsense Mutation (SNP) | VAF 38/244 reads (16%) | called by muse, mutect2, varscan2
- ZNF43 | c.952G>A p.E318K | Missense Mutation (SNP) | VAF 12/116 reads (10%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.633); called by muse, mutect2, varscan2
- ZNF480 | c.1538G>C p.C513S | Missense Mutation (SNP) | VAF 21/436 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2
- ZNF57 | c.861A>C p.K287N | Missense Mutation (SNP) | VAF 30/139 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ABCA13 | c.1632C>T p.N544= | Silent (SNP) | VAF 20/97 reads (21%) | called by muse, mutect2, varscan2
- ANTXR1 | c.828T>C p.D276= | Silent (SNP) | VAF 26/199 reads (13%) | catalogued as rs780468449; called by muse, mutect2, varscan2
- APH1A | c.729C>G p.L243= | Silent (SNP) | VAF 23/162 reads (14%) | called by muse, mutect2, varscan2
- C1orf167 | c.3579C>T p.L1193= | Silent (SNP) | VAF 16/97 reads (16%) | called by mutect2, varscan2
- CRISP1 | c.546T>C p.P182= | Silent (SNP) | VAF 7/59 reads (12%) | called by muse, mutect2, varscan2
- DDX54 | c.591T>C p.T197= | Silent (SNP) | VAF 12/108 reads (11%) | called by muse, mutect2, varscan2
- FFAR3 | c.669G>T p.V223= | Silent (SNP) | VAF 22/170 reads (13%) | called by muse, mutect2, varscan2
- GAREM1 | c.75C>A p.L25= | Silent (SNP) | VAF 27/126 reads (21%) | called by muse, mutect2, varscan2
- HADHA | c.102T>G p.A34= | Silent (SNP) | VAF 20/84 reads (24%) | called by muse, mutect2, varscan2
- LONP2 | c.2076G>A p.V692= | Silent (SNP) | VAF 15/105 reads (14%) | called by muse, mutect2, varscan2
- PCDH15 | c.4182G>A p.V1394= | Silent (SNP) | VAF 25/108 reads (23%) | catalogued as COSV57269032; called by muse, mutect2, varscan2
- PINX1 | c.873G>A p.L291= | Silent (SNP) | VAF 40/272 reads (15%) | catalogued as rs896095411; called by muse, varscan2
- PLXNC1 | c.1635C>T p.L545= | Silent (SNP) | VAF 22/139 reads (16%) | called by muse, mutect2, varscan2
- POLR3A | c.4080C>T p.F1360= | Silent (SNP) | VAF 31/188 reads (16%) | called by muse, mutect2, varscan2
- PTPN14 | c.2244C>T p.P748= | Silent (SNP) | VAF 31/267 reads (12%) | catalogued as COSV65284706; called by muse, varscan2
- PYGL | c.2472C>T p.N824= | Silent (SNP) | VAF 48/279 reads (17%) | catalogued as rs752830182; called by muse, mutect2, varscan2
- RAPGEF2 | c.735T>G p.V245= | Silent (SNP) | VAF 32/207 reads (15%) | called by muse, mutect2, varscan2
- RBM44 | c.1041A>G p.T347= (on ENST00000611254; = p.T981= on NM_001080504.2) | Silent (SNP) | VAF 11/65 reads (17%) | catalogued as rs1164265167; called by muse, mutect2, varscan2
- TRAFD1 | c.492T>A p.I164= | Silent (SNP) | VAF 25/130 reads (19%) | called by muse, mutect2, varscan2
- USH2A | c.2073C>T p.C691= | Silent (SNP) | VAF 22/202 reads (11%) | catalogued as rs376674482, CM044737; called by muse, mutect2, varscan2
- AADACL3 | c.*36T>G | 3'UTR (SNP) | VAF 31/227 reads (14%) | called by muse, mutect2, varscan2
- ABHD2 | c.*1832C>T | 3'UTR (SNP) | VAF 33/179 reads (18%) | called by muse, mutect2, varscan2
- AC025884.2 | n.516G>A | RNA (SNP) | VAF 3/52 reads (6%) | catalogued as rs900850090; called by muse, mutect2
- ADAMTS5 | c.*3085A>G | 3'UTR (SNP) | VAF 11/67 reads (16%) | called by muse, mutect2, varscan2
- ADAP2 | chr17:30921751 C>T | 5'Flank (SNP) | VAF 14/130 reads (11%) | called by muse, mutect2
- ADGRA3 | c.1809+631T>G | Intron (SNP) | VAF 11/70 reads (16%) | called by muse, mutect2, varscan2
- ADGRG6 | c.*1759G>C | 3'UTR (SNP) | VAF 16/77 reads (21%) | called by muse, mutect2, varscan2
- AGBL2 | c.*456T>G | 3'UTR (SNP) | VAF 16/134 reads (12%) | called by muse, mutect2, varscan2
- AGMAT | c.*1877T>A | 3'UTR (SNP) | VAF 3/12 reads (25%) | called by muse, mutect2
- ANKRD12 | c.*1805G>A | 3'UTR (SNP) | VAF 14/86 reads (16%) | called by muse, mutect2, varscan2
- APBA2 | c.*395C>T | 3'UTR (SNP) | VAF 33/189 reads (17%) | called by muse, mutect2, varscan2
- ARF4 | c.*578A>G | 3'UTR (SNP) | VAF 9/99 reads (9%) | called by muse, mutect2
- ARF6 | c.*50C>T | 3'UTR (SNP) | VAF 52/361 reads (14%) | called by muse, mutect2, varscan2
- ARHGEF1 | c.615-15C>T | Intron (SNP) | VAF 16/116 reads (14%) | called by muse, mutect2, varscan2
- ARL4A | chr7:12689590 ins T | 3'Flank (INS) | VAF 19/108 reads (18%) | called by mutect2, varscan2
- ART4 | c.*777C>T | 3'UTR (SNP) | VAF 7/63 reads (11%) | called by mutect2, varscan2
- ASTN2 | c.-76C>T | 5'UTR (SNP) | VAF 9/46 reads (20%) | called by muse, mutect2, varscan2
- ASXL1 | c.719-422C>T | Intron (SNP) | VAF 25/54 reads (46%) | called by muse, mutect2, varscan2
- ATP5F1C | c.-18A>T | 5'UTR (SNP) | VAF 32/163 reads (20%) | called by muse, mutect2, varscan2
- AVL9 | c.*2964C>T | 3'UTR (SNP) | VAF 20/116 reads (17%) | called by muse, mutect2, varscan2
- C20orf197 | n.536T>C | RNA (SNP) | VAF 35/279 reads (13%) | catalogued as rs1361490706; called by muse, mutect2, varscan2
- CAMKK2 | c.*1835G>A | 3'UTR (SNP) | VAF 20/102 reads (20%) | called by muse, mutect2, varscan2
- CENPP | c.*2380A>G | 3'UTR (SNP) | VAF 8/58 reads (14%) | called by muse, mutect2, varscan2
- CEP170 | c.1843+35T>A | Intron (SNP) | VAF 15/139 reads (11%) | called by muse, mutect2, varscan2
- CETP | c.598-46C>T | Intron (SNP) | VAF 16/86 reads (19%) | called by muse, mutect2, varscan2
- CFAP97 | c.1321-5155C>T | Intron (SNP) | VAF 8/64 reads (13%) | called by muse, mutect2, varscan2
- CHST13 | c.*286G>A | 3'UTR (SNP) | VAF 32/211 reads (15%) | catalogued as rs777053857; called by muse, mutect2, varscan2
- CLCN5 | chrX:50096013 G>T | 3'Flank (SNP) | VAF 21/135 reads (16%) | called by muse, mutect2, varscan2
- COG6 | c.*2483G>C | 3'UTR (SNP) | VAF 6/43 reads (14%) | called by muse, mutect2, varscan2
- CPS1 | c.4102-54A>G | Intron (SNP) | VAF 3/28 reads (11%) | called by muse, mutect2
- CREB1 | c.*1179A>G | 3'UTR (SNP) | VAF 8/75 reads (11%) | catalogued as rs1304305942; called by muse, mutect2, varscan2
- EML2 | c.21-130C>T | Intron (SNP) | VAF 5/41 reads (12%) | called by muse, mutect2, varscan2
- FEM1C | c.*263C>T | 3'UTR (SNP) | VAF 12/105 reads (11%) | catalogued as rs1180993411; called by muse, mutect2, varscan2
- GIGYF2 | c.*654G>A | 3'UTR (SNP) | VAF 8/67 reads (12%) | catalogued as rs1205102505; called by muse, mutect2, varscan2
- GNL1 | c.*1265C>T | 3'UTR (SNP) | VAF 15/96 reads (16%) | called by muse, mutect2, varscan2
- HOPX | c.*401G>A | 3'UTR (SNP) | VAF 25/136 reads (18%) | called by muse, mutect2, varscan2
- IGSF8 | chr1:160098630 C>T | 5'Flank (SNP) | VAF 66/146 reads (45%) | called by muse, mutect2, varscan2
- INSM2 | c.-5C>T | 5'UTR (SNP) | VAF 12/74 reads (16%) | called by mutect2, varscan2
- IVNS1ABP | c.1242+21G>A | Intron (SNP) | VAF 47/341 reads (14%) | called by muse, mutect2, varscan2
- KIR3DP1 | n.457G>A | RNA (SNP) | VAF 28/284 reads (10%) | called by muse, mutect2
- LINC01556 | n.345C>T | RNA (SNP) | VAF 8/56 reads (14%) | called by muse, mutect2, varscan2
- MTG1 | c.*1282C>G | 3'UTR (SNP) | VAF 22/114 reads (19%) | called by muse, mutect2, varscan2
- NAT8L | c.*2536C>T | 3'UTR (SNP) | VAF 31/167 reads (19%) | called by muse, mutect2, varscan2
- OFCC1 | n.287G>T | RNA (SNP) | VAF 9/31 reads (29%) | called by muse, mutect2, varscan2
- OFCC1 | n.286A>C | RNA (SNP) | VAF 9/32 reads (28%) | called by muse, mutect2
- PABPC5 | c.*1322A>T | 3'UTR (SNP) | VAF 8/46 reads (17%) | called by muse, mutect2, varscan2
- PATE1 | c.*461G>T | 3'UTR (SNP) | VAF 10/92 reads (11%) | called by muse, mutect2, varscan2
- PIM3 | c.86-35C>T | Intron (SNP) | VAF 17/86 reads (20%) | called by muse, mutect2, varscan2
- POGK | c.*1657T>A | 3'UTR (SNP) | VAF 21/134 reads (16%) | called by muse, mutect2, varscan2
- POU6F1 | c.*982C>T | 3'UTR (SNP) | VAF 9/55 reads (16%) | called by muse, mutect2, varscan2
- PTGES3 | c.*877G>A | 3'UTR (SNP) | VAF 21/163 reads (13%) | called by muse, mutect2, varscan2
- RAB9B | c.*577T>C | 3'UTR (SNP) | VAF 5/89 reads (6%) | called by muse, mutect2
- RDH11 | chr14:67695776 C>G | 5'Flank (SNP) | VAF 28/250 reads (11%) | called by muse, mutect2, varscan2
- RFC4 | c.132-54C>T | Intron (SNP) | VAF 21/133 reads (16%) | called by muse, mutect2, varscan2
- RNF11 | c.*2037G>A | 3'UTR (SNP) | VAF 20/98 reads (20%) | called by muse, mutect2, varscan2
- RORB | c.*262C>T | 3'UTR (SNP) | VAF 14/88 reads (16%) | catalogued as rs753112912; called by muse, mutect2, varscan2
- RTL6 | c.*1855T>C | 3'UTR (SNP) | VAF 22/175 reads (13%) | called by muse, mutect2, varscan2
- SCO1 | c.*555C>T | 3'UTR (SNP) | VAF 8/78 reads (10%) | called by muse, mutect2, varscan2
- SEC62 | c.*2066T>A | 3'UTR (SNP) | VAF 6/94 reads (6%) | called by muse, mutect2
- SEMA6D | c.*1682G>C | 3'UTR (SNP) | VAF 22/132 reads (17%) | called by muse, varscan2
- SEPSECS | c.*85T>G | 3'UTR (SNP) | VAF 7/65 reads (11%) | called by muse, mutect2, varscan2
- SLC41A2 | c.*1959G>A | 3'UTR (SNP) | VAF 12/57 reads (21%) | called by muse, mutect2, varscan2
- SLCO1A2 | c.*3084A>T | 3'UTR (SNP) | VAF 10/43 reads (23%) | called by muse, mutect2, varscan2
- SOCS5 | c.*2170A>G | 3'UTR (SNP) | VAF 15/109 reads (14%) | called by muse, mutect2, varscan2
- TKTL1 | chrX:154295736 C>A | 5'Flank (SNP) | VAF 15/106 reads (14%) | called by muse, mutect2, varscan2
- TLR2 | c.-276C>T | 5'UTR (SNP) | VAF 20/117 reads (17%) | catalogued as COSV52604833; called by muse, mutect2, varscan2
- TLR9 | c.-316G>A | 5'UTR (SNP) | VAF 26/136 reads (19%) | called by muse, mutect2, varscan2
- YWHAE | c.*511T>C | 3'UTR (SNP) | VAF 20/160 reads (13%) | called by muse, mutect2, varscan2
- ZNF385D | c.*2238C>A | 3'UTR (SNP) | VAF 8/72 reads (11%) | catalogued as rs940161681; called by muse, mutect2, varscan2
- ZNF578 | chr19:52451206 G>T | 5'Flank (SNP) | VAF 10/74 reads (14%) | called by muse, mutect2, varscan2
- ZNF747 | c.*389C>T | 3'UTR (SNP) | VAF 26/116 reads (22%) | catalogued as COSV53224863; called by muse, mutect2, varscan2
- ZNF844 | c.*3689G>A | 3'UTR (SNP) | VAF 7/95 reads (7%) | called by muse, mutect2
